Somatic mutation profile of tumor specimen TCGA-EM-A2CN-01A (aliquot TCGA-EM-A2CN-01A-11D-A19J-08) from TCGA case TCGA-EM-A2CN, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVC; Age at diagnosis: 62.5 years (22,817 days).
Specimen TCGA-EM-A2CN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33809528-5177-4f1f-bd50-a244978e0301.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2CN-10B (Blood Derived Normal), aliquot TCGA-EM-A2CN-10B-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66c61e6e-c1ea-48f4-95d5-c61e258870f4

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Nonsense Mutation 2, Silent 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 126/317 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY9 | c.1300A>C p.K434Q | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV53581609; called by muse, mutect2
- ARVCF | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs767785254, COSV54269991; called by muse, varscan2
- C11orf87 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs777533474, COSV59355978, COSV59358429; called by muse, mutect2, varscan2
- C6orf47 | c.635G>T p.R212L | Missense Mutation (SNP) | VAF 47/84 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV63264150; called by muse, mutect2, varscan2
- GRAMD2A | c.587A>C p.E196A | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.929); catalogued as COSV59035166; called by muse, mutect2
- H3C13 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs782100924, COSV58944683, COSV58944907; called by muse, mutect2, varscan2
- KCNA4 | c.1170C>A p.C390* | Nonsense Mutation (SNP) | VAF 48/126 reads (38%) | catalogued as COSV60255795; called by muse, mutect2, varscan2
- KLHL24 | c.1751A>G p.Y584C | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as rs143529905; called by muse, mutect2, varscan2
- LAMC3 | c.1363G>T p.E455* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as COSV63089190, COSV63095249; called by mutect2, varscan2
- MOB3B | c.419-2A>G p.X140_splice | Splice Site (SNP) | VAF 61/133 reads (46%) | catalogued as COSV51789784; called by muse, mutect2, varscan2
- PSMA6 | c.30C>A p.D10E | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV54839126; called by muse, mutect2
- SF3A1 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 107/226 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.057); catalogued as COSV53171194; called by muse, mutect2, varscan2
- TBC1D7 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58245033; called by muse, mutect2, varscan2
- FARP2 | c.2572_2582del p.G858Pfs*28 | Frame Shift Del (DEL) | VAF 54/166 reads (33%) | called by pindel, varscan2*
- CDHR1 | c.1815C>T p.N605= | Silent (SNP) | VAF 64/131 reads (49%) | catalogued as rs777623351, COSV60566303; called by muse, mutect2, varscan2
- FAT3 | c.11067C>T p.S3689= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs576218915, COSV53171200, COSV53192532; called by muse, mutect2, varscan2
